Somatic mutation profile of tumor specimen TCGA-JY-A939-01A (aliquot TCGA-JY-A939-01A-12D-A37C-09) from TCGA case TCGA-JY-A939, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.2 years (28,181 days).
Specimen TCGA-JY-A939-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6137fd17-bdbd-4169-93b7-9465178b6fef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A939-10A (Blood Derived Normal), aliquot TCGA-JY-A939-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bec98819-34a1-4c3d-9b27-f0f44608657b

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, 3'UTR 1, Nonsense Mutation 1, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by mutect2, varscan2
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAMTS19 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1290467557, COSV50810307, COSV99176714; called by muse, mutect2, varscan2
- ALDH8A1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143751098, COSV99665019; called by muse, mutect2, varscan2
- ATM | c.3992A>G p.Q1331R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs876658669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2C1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as CM003651; called by muse, mutect2
- FAM160B2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs770493760; called by muse, mutect2, varscan2
- FRZB | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717621; called by muse, varscan2
- KIF13A | c.5165C>T p.T1722M | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs780742333; called by muse, mutect2, varscan2
- LAT2 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.556); catalogued as rs782261695; called by muse, mutect2
- METTL2A | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.782); catalogued as rs768009312, COSV100274111; called by muse, mutect2, varscan2
- MYO9B | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs570386608; called by muse, mutect2, varscan2
- OLFM3 | c.1375G>A p.G459S (on ENST00000338858 / NM_001288821.1; = p.G439S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV58800374; called by muse, mutect2, varscan2
- PRAM1 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217990585; called by muse, mutect2, varscan2
- PTPRD | c.2024A>G p.E675G | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV100646591; called by muse, mutect2
- RYR2 | c.4466G>A p.C1489Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV63699482; called by muse, mutect2, varscan2
- SAMD9L | c.2140A>G p.S714G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.083); catalogued as rs781131220; called by mutect2, varscan2
- SDSL | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053286181; called by muse, mutect2, varscan2
- SPATA31A1 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1189751595; called by muse, mutect2
- TMEM14B | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs554783546; called by muse, mutect2, varscan2
- UGT3A2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV56930433, COSV99236981; called by muse, mutect2, varscan2
- ZNF287 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV101209398; called by muse, mutect2
- ZNF337 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs182272160, COSV99430596; called by muse, mutect2, varscan2
- ADAMTS6 | c.2997A>T p.Q999H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.2367A>C p.K789N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HCAR2 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2
- KDR | c.3127A>T p.K1043* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- KRTAP10-5 | c.193T>G p.C65G | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MUC16 | c.30158T>C p.L10053P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NOTCH4 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- POTEE | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- DLGAP2 | c.2916C>T p.N972= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs368740931; called by muse, mutect2, varscan2
- FKBP6 | c.99G>A p.S33= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs1554546814; called by muse, mutect2, varscan2
- GPR20 | c.135G>T p.L45= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1386369500; called by muse, mutect2, varscan2
- KSR2 | c.1626G>A p.P542= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs377054023; called by muse, mutect2, varscan2
- MAP2 | c.618T>G p.T206= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV52285788; called by muse, mutect2, varscan2
- MEF2C | c.252C>T p.I84= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs780952466, COSV60930537; ClinVar: likely benign; called by mutect2, varscan2
- NRXN1 | c.4146C>T p.G1382= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs587781101; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCCB | c.267A>G p.R89= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.2436G>A p.G812= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- SELENOV | c.645G>A p.P215= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs748649352, COSV100112571; called by mutect2, varscan2
- SLC5A5 | c.903C>T p.I301= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs550545031; called by mutect2, varscan2
- SPEG | c.5934G>A p.R1978= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823079 C>A | 5'Flank (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- RGS7 | c.*22T>A | 3'UTR (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- XIST | n.10510G>T | RNA (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
